Somatic mutation profile of tumor specimen TCGA-AT-A5NU-01A (aliquot TCGA-AT-A5NU-01A-11D-A28G-10) from TCGA case TCGA-AT-A5NU, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 77.0 years (28,137 days).
Specimen TCGA-AT-A5NU-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e8a13eff-01be-44ae-b433-da62ecae313d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AT-A5NU-10A (Blood Derived Normal), aliquot TCGA-AT-A5NU-10A-01D-A28G-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cb98ebe2-d27f-43d7-9128-4a7427f8953b

The open-access MAF lists 68 somatic variants for this specimen: 57 protein-altering or splice-affecting, 10 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 43, Silent 10, Frame Shift Del 5, Nonsense Mutation 4, Frame Shift Ins 3, Splice Site 2, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA7 | c.112A>T p.I38F | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54034012; called by muse, mutect2, varscan2
- ADGRV1 | c.18122C>T p.S6041L | Missense Mutation (SNP) | VAF 50/144 reads (35%) | SIFT tolerated (0.2); PolyPhen benign (0.061); catalogued as COSV67991303; called by muse, mutect2, varscan2
- AMPD2 | c.1192C>G p.R398G | Missense Mutation (SNP) | VAF 44/96 reads (46%) | SIFT tolerated (0.05); PolyPhen benign (0.026); catalogued as COSV56649450; called by muse, mutect2, varscan2
- ANAPC10 | c.534C>A p.F178L | Missense Mutation (SNP) | VAF 24/46 reads (52%) | SIFT tolerated (0.21); PolyPhen benign (0.029); catalogued as COSV58739094, COSV58740540; called by muse, mutect2, varscan2
- ARID4A | c.754A>C p.S252R | Missense Mutation (SNP) | VAF 61/139 reads (44%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.886); catalogued as COSV62165475; called by muse, mutect2, varscan2
- BVES | c.835C>T p.H279Y | Missense Mutation (SNP) | VAF 32/94 reads (34%) | SIFT tolerated (0.16); PolyPhen benign (0.116); catalogued as rs370149373; called by muse, mutect2, varscan2
- C1orf146 | c.142A>C p.I48L | Missense Mutation (SNP) | VAF 12/22 reads (55%) | SIFT tolerated (0.16); PolyPhen benign (0.117); catalogued as COSV64861151; called by muse, mutect2
- CABLES1 | c.869C>T p.S290F (on ENST00000256925 / NM_001100619.2; = p.S25F on NM_138375.2) | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV56935718; called by muse, mutect2, varscan2
- CATSPERG | c.1497-2A>T p.X499_splice | Splice Site (SNP) | VAF 31/64 reads (48%) | catalogued as COSV53051622; called by muse, mutect2, varscan2
- CDH11 | c.2104T>C p.Y702H | Missense Mutation (SNP) | VAF 110/211 reads (52%) | SIFT tolerated (0.54); PolyPhen possibly damaging (0.852); catalogued as COSV51770637; called by muse, mutect2, varscan2
- CEBPZ | c.1294A>T p.N432Y | Missense Mutation (SNP) | VAF 37/108 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs771042766, COSV50018290; called by muse, mutect2, varscan2
- CENPM | c.317G>A p.R106Q | Missense Mutation (SNP) | VAF 35/86 reads (41%) | SIFT tolerated (0.32); PolyPhen benign (0.005); catalogued as rs138744954; called by muse, mutect2, varscan2
- CREG1 | c.580A>T p.I194L | Missense Mutation (SNP) | VAF 42/96 reads (44%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.943); catalogued as COSV65148688; called by muse, mutect2, varscan2
- CRYBG3 | c.5887A>T p.K1963* | Nonsense Mutation (SNP) | VAF 140/241 reads (58%) | catalogued as COSV51714413; called by muse, varscan2
- DDX41 | c.280C>G p.L94V | Missense Mutation (SNP) | VAF 33/78 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100286474, COSV57904905; called by muse, mutect2, varscan2
- DIAPH1 | c.1966C>A p.P656T | Missense Mutation (SNP) | VAF 22/47 reads (47%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0.41); catalogued as COSV53886132; called by muse, mutect2, varscan2
- EIF3L | c.1142G>A p.R381H | Missense Mutation (SNP) | VAF 71/184 reads (39%) | SIFT tolerated (0.07); PolyPhen benign (0.067); catalogued as rs777523428, COSV67739885; called by muse, mutect2, varscan2
- ENTHD1 | c.43T>G p.S15A | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as COSV57323064; called by muse, mutect2, varscan2
- GCC2 | c.2094T>A p.S698R | Missense Mutation (SNP) | VAF 36/156 reads (23%) | SIFT tolerated (0.53); PolyPhen benign (0.039); catalogued as COSV59178588; called by muse, mutect2, varscan2
- GPR155 | c.1208T>C p.L403S | Missense Mutation (SNP) | VAF 44/136 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV55040765; called by muse, mutect2, varscan2
- GTF2B | c.124G>C p.G42R | Missense Mutation (SNP) | VAF 36/75 reads (48%) | SIFT deleterious (0.02); PolyPhen benign (0.047); catalogued as COSV65137445; called by muse, mutect2, varscan2
- HDAC6 | c.2141A>G p.D714G | Missense Mutation (SNP) | VAF 69/79 reads (87%) | SIFT deleterious (0); PolyPhen possibly damaging (0.848); catalogued as COSV61929912; called by muse, mutect2, varscan2
- HSPA9 | c.644A>G p.N215S | Missense Mutation (SNP) | VAF 7/67 reads (10%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.05); catalogued as COSV51865557; called by muse, mutect2, varscan2
- JADE2 | c.453C>A p.N151K | Missense Mutation (SNP) | VAF 52/117 reads (44%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV50924407; called by muse, mutect2, varscan2
- KEL | c.1530C>A p.S510R | Missense Mutation (SNP) | VAF 8/196 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.648); catalogued as COSV62336697; called by muse, mutect2
- LAMB1 | c.1634C>G p.P545R | Missense Mutation (SNP) | VAF 68/185 reads (37%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.553); catalogued as COSV55968093; called by muse, mutect2, varscan2
- LAMB2 | c.3646C>G p.Q1216E | Missense Mutation (SNP) | VAF 53/76 reads (70%) | SIFT tolerated (0.5); PolyPhen benign (0.01); catalogued as COSV59736056; called by muse, mutect2, varscan2
- LRFN2 | c.1264C>A p.P422T | Missense Mutation (SNP) | VAF 22/52 reads (42%) | SIFT tolerated (0.3); PolyPhen benign (0.03); catalogued as COSV57831630; called by muse, mutect2, varscan2
- MAEA | c.573G>T p.K191N | Missense Mutation (SNP) | VAF 39/95 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV53263885; called by muse, mutect2, varscan2
- MFSD11 | c.437+1G>A p.X146_splice | Splice Site (SNP) | VAF 10/180 reads (6%) | catalogued as COSV60626367; called by muse, mutect2
- MMS22L | c.2046G>A p.M682I | Missense Mutation (SNP) | VAF 42/117 reads (36%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as rs747622217, COSV51521613; called by muse, mutect2, varscan2
- NT5DC3 | c.1022C>G p.P341R | Missense Mutation (SNP) | VAF 43/97 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV67322353; called by muse, mutect2, varscan2
- ORC4 | c.1073A>T p.Q358L | Missense Mutation (SNP) | VAF 8/156 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.122); catalogued as COSV51575643, COSV99932395; called by muse, mutect2
- PARP15 | c.1855C>T p.R619* (on ENST00000464300 / NM_001113523.3; = p.R385* on NM_152615.2) | Nonsense Mutation (SNP) | VAF 50/161 reads (31%) | catalogued as rs764796896, COSV59973982; called by muse, mutect2, varscan2
- PCYOX1L | c.1166A>T p.Q389L | Missense Mutation (SNP) | VAF 39/100 reads (39%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.874); catalogued as rs1168857081, COSV51003985; called by muse, mutect2, varscan2
- PKP4 | c.246C>A p.S82R | Missense Mutation (SNP) | VAF 23/97 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.18); catalogued as COSV67678484; called by muse, mutect2, varscan2
- RARS1 | c.1441G>T p.E481* | Nonsense Mutation (SNP) | VAF 46/116 reads (40%) | catalogued as COSV51562156, COSV51565564; called by muse, mutect2, varscan2
- SAP30BP | c.689G>C p.G230A | Missense Mutation (SNP) | VAF 21/54 reads (39%) | SIFT tolerated (0.06); PolyPhen benign (0.351); catalogued as COSV53129197; called by muse, mutect2, varscan2
- SERPINA7 | c.275T>C p.I92T | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs767983003, COSV59666695; called by muse, mutect2, varscan2
- SLF2 | c.181C>T p.Q61* | Nonsense Mutation (SNP) | VAF 19/51 reads (37%) | catalogued as rs756447299, COSV53277023; called by muse, mutect2, varscan2
- SPATA6 | c.70G>A p.V24M | Missense Mutation (SNP) | VAF 28/66 reads (42%) | SIFT tolerated (0.12); PolyPhen benign (0.052); catalogued as rs777236752, COSV64062426; called by muse, mutect2, varscan2
- SUPT5H | c.3084G>C p.E1028D | Missense Mutation (SNP) | VAF 10/88 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV58680140; called by muse, mutect2
- TCIRG1 | c.2015A>G p.E672G | Missense Mutation (SNP) | VAF 35/67 reads (52%) | SIFT tolerated (0.31); PolyPhen benign (0.001); catalogued as COSV55836798; called by muse, mutect2, varscan2
- TENM1 | c.3331C>A p.P1111T | Missense Mutation (SNP) | VAF 121/140 reads (86%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as COSV64438420; called by muse, mutect2, varscan2
- TRPM1 | c.1328T>A p.V443E | Missense Mutation (SNP) | VAF 37/94 reads (39%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as rs771408602, COSV56638817; called by muse, mutect2, varscan2
- TTC8 | c.1316C>T p.A439V (on ENST00000338104 / NM_001288781.1; = p.A423V on NM_144596.4) | Missense Mutation (SNP) | VAF 51/110 reads (46%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.571); catalogued as COSV57629109; called by muse, mutect2, varscan2
- WDR11 | c.3397T>A p.S1133T | Missense Mutation (SNP) | VAF 45/111 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV54790951; called by muse, mutect2, varscan2
- ZNF181 | c.371T>C p.I124T | Missense Mutation (SNP) | VAF 27/99 reads (27%) | SIFT tolerated (0.35); PolyPhen benign (0.001); catalogued as COSV67627054; called by muse, mutect2, varscan2
- ZNF697 | c.1571C>T p.A524V | Missense Mutation (SNP) | VAF 35/80 reads (44%) | SIFT tolerated (0.21); PolyPhen benign (0.059); catalogued as rs868197050, COSV70284241; called by muse, mutect2, varscan2
- ASAH1 | c.966del p.E322Dfs*36 | Frame Shift Del (DEL) | VAF 23/68 reads (34%) | called by mutect2, pindel, varscan2
- CDC42BPG | c.1424_1436del p.G475Vfs*65 | Frame Shift Del (DEL) | VAF 26/69 reads (38%) | called by mutect2, pindel, varscan2
- CITED2 | c.773_782del p.D258Afs*8 | Frame Shift Del (DEL) | VAF 21/59 reads (36%) | called by mutect2, pindel, varscan2
- NEB | c.624dup p.E209* | Frame Shift Ins (INS) | VAF 56/125 reads (45%) | called by mutect2, pindel, varscan2
- OR5T2 | c.89_90del p.F30Yfs*17 | Frame Shift Del (DEL) | VAF 34/94 reads (36%) | called by mutect2, pindel, varscan2
- RENBP | c.1122dup p.E375Rfs*? | Frame Shift Ins (INS) | VAF 121/187 reads (65%) | called by mutect2, pindel, varscan2
- SEC14L2 | c.1209dup p.*404Ifs*30 | Frame Shift Ins (INS) | VAF 18/57 reads (32%) | called by mutect2, pindel, varscan2
- SERPINF1 | c.910_916del p.E304Rfs*12 | Frame Shift Del (DEL) | VAF 76/133 reads (57%) | called by mutect2, pindel, varscan2
- AC004922.1 | c.1611A>G p.V537= | Silent (SNP) | VAF 50/90 reads (56%) | catalogued as COSV53164306; called by muse, mutect2, varscan2
- ADAMTS12 | c.1125T>C p.S375= | Silent (SNP) | VAF 10/166 reads (6%) | catalogued as COSV61271729; called by muse, mutect2
- AQR | c.2268A>C p.G756= | Silent (SNP) | VAF 28/70 reads (40%) | catalogued as COSV50043311; called by muse, mutect2, varscan2
- CATIP | c.270C>T p.A90= | Silent (SNP) | VAF 34/69 reads (49%) | catalogued as COSV56823784; called by muse, mutect2, varscan2
- CFAP52 | c.582C>A p.I194= | Silent (SNP) | VAF 14/49 reads (29%) | catalogued as COSV55347483; called by muse, mutect2, varscan2
- FBXL13 | c.927C>T p.F309= | Silent (SNP) | VAF 35/155 reads (23%) | catalogued as COSV50866294; called by muse, mutect2, varscan2
- PPM1N | c.306C>T p.L102= | Silent (SNP) | VAF 10/64 reads (16%) | catalogued as rs774525986, COSV55593450, COSV55595252; called by muse, mutect2
- SLIT2 | c.1749T>A p.G583= | Silent (SNP) | VAF 68/269 reads (25%) | catalogued as COSV56585307; called by muse, varscan2
- SPIN2B | c.531T>A p.L177= | Silent (SNP) | VAF 69/82 reads (84%) | catalogued as COSV99328178; called by mutect2, varscan2
- TRPC7 | c.2073A>T p.R691= | Silent (SNP) | VAF 43/89 reads (48%) | catalogued as COSV61460934; called by muse, mutect2, varscan2
- MAP9 | c.*2A>C | 3'UTR (SNP) | VAF 35/132 reads (27%) | catalogued as COSV100251010; called by muse, mutect2, varscan2
